Somatic mutation profile of tumor specimen ALCH-B24X-TTP1-A (aliquot ALCH-B24X-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B24X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 77.2 years (28,210 days).
Specimen ALCH-B24X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3d16b51-a790-499e-9357-bed0e329ffbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24X-NB1-A (Blood Derived Normal), aliquot ALCH-B24X-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0f0c22f-2609-4149-b2e5-be0151a807c7

The open-access MAF lists 59 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 4, Intron 2, RNA 1, 5'Flank 1, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1064795280, COSV62716575; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- MET | c.3008A>G p.Y1003C | Missense Mutation (SNP) | VAF 73/455 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100577167, COSV59258910, COSV59262717; called by muse, mutect2, varscan2
- BTK | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 81/791 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM040690; called by muse, mutect2, varscan2
- CDH7 | c.1751A>G p.D584G | Missense Mutation (SNP) | VAF 67/906 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.212); catalogued as rs1568226974; called by muse, mutect2
- GPRC6A | c.1625G>T p.C542F | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159186185; called by muse, mutect2
- GSDME | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 350/1226 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV61651668; called by muse, varscan2
- KMO | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 21/441 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100844827, COSV63809435; called by muse, mutect2
- KMT2A | c.8342A>G p.D2781G | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as rs1040253228; called by muse, mutect2
- L1CAM | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as CM003679; called by muse, mutect2
- LMTK3 | c.2268del p.P757Rfs*101 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | catalogued as rs1265678262, COSV54309598; called by pindel, varscan2
- LRRC28 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100113929; called by muse, mutect2
- NTSR1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs781334373; called by muse, mutect2
- OR2T2 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 72/1604 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1460506568; called by muse, mutect2
- SEMA4A | c.1769A>G p.Y590C | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs766568386; called by muse, mutect2, varscan2
- TAZ | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM024251, CM970426; called by muse, mutect2
- TENM2 | c.2362C>T p.R788* (on ENST00000518659 / NM_001122679.2; = p.R556* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 44/573 reads (8%) | catalogued as rs992782123; called by muse, mutect2
- TRPC5 | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1276061241; called by muse, mutect2
- ZNF770 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs779657243; called by muse, mutect2
- APC2 | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- APLF | c.1455G>A p.W485* | Nonsense Mutation (SNP) | VAF 22/367 reads (6%) | called by muse, mutect2
- ARID2 | c.1078dup p.T360Nfs*9 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- CPM | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 35/1105 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- ELOA2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.021); called by muse, mutect2
- EPX | c.77-2A>T p.X26_splice | Splice Site (SNP) | VAF 44/516 reads (9%) | called by muse, mutect2
- FLNA | c.5900C>A p.S1967Y (on ENST00000369850 / NM_001110556.2; = p.S1959Y on NM_001456.3) | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GABRB3 | c.1204T>A p.Y402N | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- GSDME | c.458A>C p.E153A | Missense Mutation (SNP) | VAF 264/1082 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, varscan2
- KANSL1 | c.3067G>T p.E1023* (on ENST00000574590 / NM_001193465.2; = p.E1024* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 31/424 reads (7%) | called by muse, mutect2
- MIB1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MLF1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); called by muse, mutect2
- NR2E3 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2
- OR5B3 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PCDH18 | c.3039G>T p.Q1013H | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH7 | c.1207C>G p.L403V | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2
- R3HCC1L | c.1917T>G p.D639E (on ENST00000612478 / NM_001256619.2; = p.D625E on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.065); called by muse, mutect2
- RNF125 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SFXN3 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2
- STAB1 | c.5270C>G p.S1757C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); called by muse, varscan2
- TNKS1BP1 | c.4637A>G p.Q1546R | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ZNF7 | c.460A>C p.N154H | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- EMILIN2 | c.2544G>T p.T848= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs563986921; called by muse, mutect2
- FRMPD3 | c.2796G>A p.E932= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as rs1173063027; called by muse, mutect2, varscan2
- HHATL | c.1437C>T p.G479= | Silent (SNP) | VAF 30/383 reads (8%) | catalogued as rs142843734; called by muse, mutect2
- HOXA6 | c.687A>G p.A229= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- ID2 | c.204C>T p.V68= | Silent (SNP) | VAF 38/510 reads (7%) | catalogued as rs1403569516; called by muse, mutect2
- MDH1B | c.930T>C p.I310= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2
- OR2L2 | c.162C>A p.L54= | Silent (SNP) | VAF 34/314 reads (11%) | catalogued as COSV63551084, COSV63555442; called by muse, mutect2, varscan2
- SCML2 | c.990T>C p.S330= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
- SOX14 | c.75G>A p.K25= | Silent (SNP) | VAF 42/522 reads (8%) | catalogued as COSV100048051; called by muse, mutect2
- SP100 | c.795C>G p.P265= | Silent (SNP) | VAF 13/257 reads (5%) | called by muse, mutect2
- TBX2 | c.252G>T p.P84= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs763177220; called by muse, varscan2
- UBE2QL1 | c.483C>T p.G161= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- ABCD1 | c.*38G>T | 3'UTR (SNP) | VAF 10/70 reads (14%) | catalogued as rs1270207448; called by muse, mutect2
- AL133467.5 | chr14:95663617 C>T | 3'Flank (SNP) | VAF 27/265 reads (10%) | called by muse, mutect2, varscan2
- CXCR2P1 | n.1054C>T | RNA (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- GALNS | c.-24G>T | 5'UTR (SNP) | VAF 33/338 reads (10%) | called by muse, mutect2
- REXO1L1P | chr8:85663477 G>T | 5'Flank (SNP) | VAF 38/2805 reads (1%) | catalogued as rs1221020824; called by muse, mutect2
- SDHA | c.1552-48G>C | Intron (SNP) | VAF 35/344 reads (10%) | called by muse, mutect2, varscan2
- TRMU | c.1019-34G>A | Intron (SNP) | VAF 44/378 reads (12%) | called by muse, mutect2, varscan2
